Somatic mutation profile of tumor specimen 0DOA3N from CCDI case PBBXNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,761 days).
Specimen 0DOA3N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18471796-5d9c-415b-8216-cbe83412d7f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA24 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af4fb77b-7b27-4dc4-bdd7-13443628c338

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TEX13A | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2
- TRIM13 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 13/399 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR1J2 | c.390C>A p.L130= | Silent (SNP) | VAF 79/351 reads (23%) | called by muse, mutect2, varscan2
- RETNLB | c.270A>G p.E90= | Silent (SNP) | VAF 24/469 reads (5%) | called by muse, mutect2
- PCSK6 | c.*54C>A | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
